FM case AD12767 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/28966cc0-f206-4e7a-baf7-7dfdb152f546

Male, 83.8 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the lung; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
